Somatic mutation profile of tumor specimen TCGA-55-8094-01A (aliquot TCGA-55-8094-01A-11D-2238-08) from TCGA case TCGA-55-8094, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 51.8 years (18,903 days).
Specimen TCGA-55-8094-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ca72b82-9c92-4c43-ad66-a0d2a6756cc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8094-10A (Blood Derived Normal), aliquot TCGA-55-8094-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed127c0c-4eea-4685-8ccf-b4706cab0dfa

The open-access MAF lists 496 somatic variants for this specimen: 367 protein-altering or splice-affecting, 117 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 317, Silent 117, Nonsense Mutation 21, Splice Site 11, Frame Shift Del 11, Frame Shift Ins 6, Intron 6, RNA 3, 5'UTR 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 127/177 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 97/110 reads (88%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12311T>C p.L4104P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101446917; called by muse, mutect2, varscan2
- ABCA4 | c.3743G>T p.R1248I | Missense Mutation (SNP) | VAF 77/127 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV100933108, COSV100933340; called by muse, mutect2, varscan2
- ABCA5 | c.868T>G p.L290V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV101201115, COSV101201176; called by muse, mutect2
- ABLIM3 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV100448295; called by muse, mutect2, varscan2
- ADAM23 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100007376; called by muse, mutect2, varscan2
- ADAMTS12 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100711384, COSV61255573; called by muse, mutect2, varscan2
- ADAMTS12 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.203); catalogued as COSV100710747; called by muse, mutect2
- ADCY8 | c.3185C>T p.A1062V | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.826); catalogued as rs1171546317, COSV99651839; called by muse, mutect2, varscan2
- ADGRB1 | c.1567G>T p.G523C | Missense Mutation (SNP) | VAF 69/87 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100029548; called by muse, mutect2, varscan2
- ADGRB3 | c.2092A>G p.M698V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101000409; called by muse, mutect2, varscan2
- ADGRL2 | c.4286A>G p.N1429S (on ENST00000370717 / NM_001366005.1; = p.N1373S on NM_012302.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99588519; called by muse, mutect2, varscan2
- ADIPOR1 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as COSV100579496; called by muse, mutect2, varscan2
- ADIPOR1 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 94/217 reads (43%) | catalogued as COSV100579497, COSV61851379; called by muse, mutect2, varscan2
- AKR1B10 | c.730dup p.T244Nfs*29 | Frame Shift Ins (INS) | VAF 15/86 reads (17%) | catalogued as rs1333065534; called by mutect2, varscan2
- AL592490.1 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV101308165; called by muse, mutect2, varscan2
- ALPK1 | c.431C>G p.A144G | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); catalogued as COSV99453909; called by muse, mutect2, varscan2
- ANK2 | c.8449A>T p.T2817S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.053); catalogued as COSV100001134; called by muse, mutect2, varscan2
- ANKRD2 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV100080818; called by muse, mutect2, varscan2
- ANXA2 | c.334del p.S112Lfs*3 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs752359543; called by mutect2, pindel, varscan2
- AP1M2 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140806; called by muse, mutect2, varscan2
- AP3D1 | c.1829A>T p.K610M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100642628; called by muse, mutect2, varscan2
- APOB | c.9943C>A p.L3315I | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV51959828; called by muse, mutect2, varscan2
- ASCL3 | c.270C>A p.Y90* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV57941022, COSV57941155, COSV57941437; called by muse, mutect2, varscan2
- ASIC5 | c.1510G>T p.E504* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV101611127; called by muse, mutect2
- ASPA | c.252A>C p.E84D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99559207; called by muse, mutect2, varscan2
- ASRGL1 | c.576A>T p.K192N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100077825; called by muse, mutect2, varscan2
- ASXL3 | c.3464C>G p.S1155W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99324595, COSV99324757; called by muse, mutect2, varscan2
- ATG9B | c.1772A>G p.Q591R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as COSV99871553; called by muse, mutect2, varscan2
- ATG9B | c.1771C>A p.Q591K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.089); catalogued as COSV99871554; called by muse, mutect2, varscan2
- ATP7B | c.26C>G p.T9R | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99666344; called by muse, mutect2, varscan2
- ATP8A2 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99681462; called by muse, mutect2, varscan2
- BCHE | c.931G>T p.G311W | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV100012168; called by muse, mutect2, varscan2
- BCHE | c.930T>A p.Y310* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV100012409; called by muse, mutect2, varscan2
- BCL9L | c.2284G>T p.D762Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV99419111; called by muse, mutect2, varscan2
- BTN3A2 | c.727A>T p.R243W | Missense Mutation (SNP) | VAF 70/131 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100709627; called by muse, mutect2, varscan2
- C10orf62 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV101035259; called by muse, mutect2, varscan2
- C12orf40 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as COSV100209973; called by muse, mutect2, varscan2
- C1QB | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100152748; called by muse, mutect2, varscan2
- C1orf94 | c.801G>T p.K267N (on ENST00000488417 / NM_001134734.2; = p.K77N on NM_032884.5) | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV100974843, COSV64913344; called by muse, mutect2, varscan2
- CALHM1 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100324214; called by muse, mutect2, varscan2
- CARD14 | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100712541; called by muse, mutect2, varscan2
- CASS4 | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs527807357, COSV100824650; called by muse, varscan2
- CASS4 | c.1440C>A p.H480Q | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV100824651; called by muse, varscan2
- CBLIF | c.737G>A p.C246Y | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99950879; called by muse, mutect2, varscan2
- CCDC15 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 38/97 reads (39%) | catalogued as COSV100776963; called by muse, mutect2, varscan2
- CCDC150 | c.1424A>G p.E475G | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV99776819; called by muse, mutect2, varscan2
- CCKBR | c.1159C>A p.P387T | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762933442, COSV100582892; called by muse, mutect2, varscan2
- CD200R1L | c.686G>T p.R229I | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.459); catalogued as COSV101236573; called by muse, mutect2, varscan2
- CD300LG | c.833-1G>T p.X278_splice | Splice Site (SNP) | VAF 48/103 reads (47%) | catalogued as COSV99517379; called by muse, mutect2, varscan2
- CD5L | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 141/432 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100941040, COSV63822760; called by muse, mutect2, varscan2
- CDH18 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV99934058; called by muse, mutect2, varscan2
- CENPF | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100871662; called by muse, mutect2, varscan2
- CENPJ | c.3163A>T p.R1055* | Nonsense Mutation (SNP) | VAF 60/151 reads (40%) | catalogued as COSV101121501; called by muse, mutect2, varscan2
- CEP250 | c.5626G>T p.A1876S | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100698887; called by muse, mutect2, varscan2
- CES1 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs773532151, COSV100828640; called by muse, mutect2
- CETP | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV99569996; called by muse, mutect2, varscan2
- CFH | c.2186G>T p.R729I | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100809411; called by muse, mutect2, varscan2
- CLEC7A | c.673G>T p.V225L (on ENST00000304084 / NM_197947.3; = p.V179L on NM_022570.5) | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV53720809, COSV53723134; called by muse, mutect2, varscan2
- CNTN1 | c.477_478insA p.P160Tfs*8 | Frame Shift Ins (INS) | VAF 13/91 reads (14%) | catalogued as COSV100751270; called by mutect2, pindel, varscan2
- CNTNAP2 | c.1157T>A p.V386E | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV100665664; called by muse, mutect2, varscan2
- COL1A2 | c.3337G>A p.D1113N | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.425); catalogued as rs760490617, COSV51964152; called by muse, mutect2, varscan2
- COLQ | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.33); PolyPhen benign (0.38); catalogued as COSV101082180; called by muse, mutect2, varscan2
- CSMD3 | c.2780C>A p.A927D (on ENST00000297405 / NM_001363185.1; = p.A823D on NM_052900.3) | Missense Mutation (SNP) | VAF 55/80 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99832217; called by muse, mutect2, varscan2
- CSTF1 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 86/357 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99410165; called by muse, mutect2, varscan2
- CTNNA2 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.055); catalogued as rs371923353, COSV100783484; called by muse, mutect2, varscan2
- CTSH | c.847G>T p.V283L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99585468; called by muse, mutect2, varscan2
- CUL2 | c.2064G>T p.M688I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101039139; called by muse, varscan2
- CYP24A1 | c.1030C>G p.R344G | Missense Mutation (SNP) | VAF 65/101 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99398252; called by muse, mutect2, varscan2
- DIO2 | c.158G>C p.R53P | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV101375865, COSV70445729; called by muse, mutect2, varscan2
- DIP2C | c.4241G>T p.R1414L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99791294; called by muse, mutect2, varscan2
- DIS3 | c.1031G>T p.R344I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV100899871, COSV66707448; called by muse, mutect2, varscan2
- DLGAP3 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 40/60 reads (67%) | catalogued as COSV99332525; called by muse, mutect2, varscan2
- DNAH9 | c.7833C>A p.S2611R | Missense Mutation (SNP) | VAF 112/589 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99305459; called by muse, mutect2, varscan2
- DNHD1 | c.11714G>T p.S3905I | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV99599952; called by muse, mutect2, varscan2
- DRC7 | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 87/353 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100395561; called by muse, mutect2, varscan2
- DSG4 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.349); catalogued as COSV100355772, COSV57395056; called by muse, mutect2, varscan2
- DUSP26 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV99823406; called by muse, mutect2, varscan2
- ELP4 | c.852G>T p.K284N (on ENST00000350638; = p.K283N on NM_019040.5) | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV100635374, COSV63359030; called by muse, mutect2, varscan2
- ELP5 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs781456383, COSV59709055; called by muse, mutect2, varscan2
- EMILIN2 | c.709A>T p.T237S | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99598445; called by muse, mutect2, varscan2
- EP400 | c.5332A>T p.M1778L | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100201053; called by muse, mutect2, varscan2
- EPB42 | c.813G>T p.L271F (on ENST00000441366 / NM_001114134.2; = p.L301F on NM_000119.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as COSV100281925; called by muse, mutect2, varscan2
- EPHA5 | c.1303A>T p.T435S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.581); catalogued as COSV99898311; called by muse, mutect2, varscan2
- EPHB6 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV100844263, COSV63893534; called by muse, mutect2, varscan2
- ESR2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV50828466; called by muse, mutect2, varscan2
- F13A1 | c.1760C>A p.A587E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99341912, COSV99342801; called by muse, mutect2, varscan2
- F5 | c.5206C>A p.P1736T | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.297); catalogued as rs779750353, COSV100889064; called by muse, mutect2, varscan2
- FAM135B | c.2733G>T p.L911F | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99422860, COSV99427524; called by muse, mutect2, varscan2
- FAM184A | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100137692; called by muse, mutect2, varscan2
- FAM209B | c.149A>T p.E50V | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100990951; called by muse, mutect2, varscan2
- FBN1 | c.2777G>T p.C926F | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM065180, CM157679, COSV100354695; called by muse, mutect2, varscan2
- FLG | c.11654G>T p.R3885I | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as COSV100911490; called by muse, mutect2, varscan2
- FLG | c.3796C>A p.Q1266K | Missense Mutation (SNP) | VAF 243/707 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV64241504; called by muse, mutect2, varscan2
- FLNC | c.2485T>C p.F829L | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100367977; called by muse, mutect2, varscan2
- FMO2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV99269077; called by muse, mutect2, varscan2
- FPGT | c.649G>T p.G217* | Nonsense Mutation (SNP) | VAF 50/79 reads (63%) | catalogued as COSV100907168; called by muse, mutect2, varscan2
- FRMD4A | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99198478; called by muse, mutect2, varscan2
- FTSJ1 | c.422A>T p.N141I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99191395; called by muse, mutect2, varscan2
- GABPB1 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as COSV55015652; called by muse, mutect2, varscan2
- GABRA4 | c.737T>G p.M246R | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99973935; called by muse, mutect2, varscan2
- GALNT17 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV61190800, COSV61192530; called by muse, mutect2, varscan2
- GATA6 | c.1750G>T p.V584L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.101); catalogued as COSV99333136; called by muse, mutect2, varscan2
- GCM1 | c.76-2A>G p.X26_splice | Splice Site (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99452308; called by muse, mutect2, varscan2
- GHR | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100050510; called by muse, mutect2, varscan2
- GNG8 | c.187A>C p.K63Q | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV100340077; called by muse, mutect2, varscan2
- GPNMB | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777412652, COSV99326451; called by muse, mutect2, varscan2
- GUSB | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as COSV100512590; called by muse, mutect2
- H2BW1 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.105); catalogued as rs374841129, COSV99475044; called by muse, mutect2, varscan2
- HACE1 | c.1536G>A p.M512I | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV99493574; called by muse, mutect2, varscan2
- HFM1 | c.344C>A p.S115* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV99645869; called by mutect2, varscan2
- HGF | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs374484762, COSV55959117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMCN1 | c.5345A>G p.K1782R | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV99628071; called by muse, mutect2, varscan2
- HTR3E | c.1016A>T p.Q339L (on ENST00000415389 / NM_001256613.1; = p.Q354L on NM_182589.2) | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100093966; called by muse, mutect2, varscan2
- IFNA10 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 75/116 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99497455; called by muse, mutect2, varscan2
- IGF2BP1 | c.1321-1G>T p.X441_splice | Splice Site (SNP) | VAF 101/254 reads (40%) | catalogued as COSV99288581; called by muse, mutect2, varscan2
- IGFBP2 | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV99288396; called by muse, mutect2, varscan2
- IGHMBP2 | c.2857G>T p.G953C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775514650, COSV99662014, COSV99662669; called by muse, mutect2, varscan2
- IGKV3D-20 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs376428800; called by muse, mutect2, varscan2
- IGSF11 | c.180G>T p.M60I (on ENST00000393775 / NM_001015887.3; = p.M59I on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV100677248; called by muse, mutect2, varscan2
- IL1F10 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs909545130, COSV100520160; called by muse, mutect2, varscan2
- IL2 | c.148-1G>C p.X50_splice | Splice Site (SNP) | VAF 23/50 reads (46%) | catalogued as COSV99900757; called by muse, mutect2, varscan2
- IL2 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1276833593, COSV99900759; called by muse, mutect2, varscan2
- IL26 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 92/301 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV57488516; called by muse, mutect2, varscan2
- ITGA2 | c.1139A>T p.Q380L | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99670643; called by muse, mutect2
- ITGAX | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99191637; called by muse, mutect2
- ITK | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101439837, COSV70063573; called by muse, mutect2, varscan2
- IVNS1ABP | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.225); catalogued as rs370542961; called by muse, mutect2, varscan2
- KCNA1 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as COSV101230208; called by muse, mutect2, varscan2
- KCNJ1 | c.354C>A p.H118Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV100131310; called by muse, mutect2, varscan2
- KCNJ16 | c.44C>A p.A15E | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV99388170; called by muse, mutect2, varscan2
- KDM4A | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100969471; called by muse, mutect2, varscan2
- KDM4D | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100624219; called by muse, mutect2, varscan2
- KDR | c.1138G>T p.G380W | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV99817429; called by muse, mutect2, varscan2
- KEAP1 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99407690; called by muse, mutect2, varscan2
- KIF1A | c.652C>A p.H218N | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100240689; called by muse, varscan2
- KIR2DL3 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 97/291 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs560363669, COSV100667812; called by muse, mutect2, varscan2
- KIR3DL1 | c.1272T>A p.D424E | Missense Mutation (SNP) | VAF 114/317 reads (36%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.952); catalogued as COSV58493291; called by muse, mutect2, varscan2
- KLF17 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV64856234; called by muse, mutect2, varscan2
- KRT77 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527065; called by muse, mutect2, varscan2
- KRTAP10-8 | c.166T>C p.C56R | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100553143; called by muse, mutect2, varscan2
- KRTAP11-1 | c.80C>A p.T27N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV100190604; called by muse, mutect2, varscan2
- L3MBTL4 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 79/255 reads (31%) | catalogued as COSV53114218, COSV99528638; called by muse, mutect2, varscan2
- LAMA2 | c.2899T>A p.C967S | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101370386; called by muse, mutect2, varscan2
- LAMA5 | c.5605C>G p.H1869D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99439508; called by muse, mutect2, varscan2
- LAMB1 | c.1754G>T p.G585V | Missense Mutation (SNP) | VAF 112/209 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99740556; called by muse, mutect2, varscan2
- LAMC1 | c.2402-2A>T p.X801_splice | Splice Site (SNP) | VAF 42/184 reads (23%) | catalogued as COSV99279449; called by muse, mutect2, varscan2
- LAMP3 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99660504; called by muse, mutect2, varscan2
- LCT | c.2679C>A p.F893L | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as COSV51544858, COSV99928479; called by muse, mutect2, varscan2
- LMBRD2 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99682786; called by muse, mutect2, varscan2
- LMX1A | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 100/182 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV54225129, COSV99672106; called by muse, mutect2, varscan2
- LRFN2 | c.963C>A p.H321Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100599474; called by muse, mutect2, varscan2
- LRGUK | c.1423G>T p.V475L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99604062; called by muse, mutect2, varscan2
- LRP2 | c.4801T>A p.C1601S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99787990; called by muse, mutect2, varscan2
- LRRIQ3 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV100598704, COSV63049804; called by muse, mutect2, varscan2
- LRRTM1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.479); catalogued as COSV99702341; called by muse, mutect2, varscan2
- MAGEE2 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.378); catalogued as COSV100973061; called by muse, mutect2, varscan2
- MAP3K4 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 98/120 reads (82%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV100815288; called by muse, mutect2, varscan2
- MARCHF6 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 110/1025 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99929571; called by muse, mutect2, varscan2
- MCC | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.447); catalogued as COSV101342724; called by muse, mutect2, varscan2
- MCOLN2 | c.556G>T p.V186F | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs369306344, COSV99393796; called by muse, mutect2, varscan2
- MEGF10 | c.1290T>G p.C430W | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99174879; called by muse, mutect2, varscan2
- MIDN | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV56296120; called by muse, mutect2, varscan2
- MNDA | c.161A>G p.K54R | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as COSV100933313; called by muse, mutect2, varscan2
- MROH6 | c.1048A>G p.M350V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1240425321, COSV52788994; called by muse, mutect2, varscan2
- MTCL1 | c.5101G>A p.E1701K (on ENST00000306329 / NM_001378206.1; = p.E1382K on NM_015210.4) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100094261, COSV60408911; called by muse, mutect2, varscan2
- MTNR1A | c.297C>A p.H99Q | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.088); catalogued as COSV100208190; called by muse, mutect2, varscan2
- MUC17 | c.3061A>G p.S1021G | Missense Mutation (SNP) | VAF 179/1132 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV100072884; called by muse, mutect2, varscan2
- MUC5B | c.6173G>C p.G2058A | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101500270; called by muse, mutect2, varscan2
- MYO10 | c.5588G>A p.R1863H | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs563993750, COSV99945196; called by muse, mutect2
- MYO15A | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99232371; called by muse, mutect2, varscan2
- MYO1F | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100596626; called by muse, mutect2, varscan2
- MYO7A | c.4976G>T p.R1659L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as COSV101289106, COSV101289115; called by muse, mutect2
- MYRIP | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs778609132, COSV100218911; called by muse, mutect2, varscan2
- MYT1L | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV101220381, COSV67712053; called by muse, mutect2, varscan2
- NAV2 | c.7341+2T>G p.X2447_splice (on ENST00000396087 / NM_001244963.2; = p.X2388_splice on NM_145117.5) | Splice Site (SNP) | VAF 11/38 reads (29%) | catalogued as COSV60660255; called by muse, mutect2, varscan2
- NAV3 | c.6893C>G p.P2298R (on ENST00000397909 / NM_001024383.2; = p.P2276R on NM_014903.6) | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99889844; called by muse, mutect2, varscan2
- NDST4 | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52116494; called by muse, mutect2, varscan2
- NECAB2 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.897); catalogued as rs753504247, COSV100533845; called by muse, mutect2, varscan2
- NEFM | c.1440G>T p.L480F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV55332857, COSV99647210; called by muse, mutect2, varscan2
- NEFM | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV99647211, COSV99647322; called by muse, mutect2, varscan2
- NEU2 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99290536; called by muse, mutect2, varscan2
- NEXMIF | c.1886A>T p.K629I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99280549; called by muse, mutect2
- NFAT5 | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 164/546 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100590701; called by muse, varscan2
- NLRP3 | c.75G>T p.M25I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as COSV100275840; called by muse, mutect2, varscan2
- NLRP4 | c.1313T>G p.L438R | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100016167; called by muse, mutect2, varscan2
- NNT | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM158499, COSV52925143; called by muse, mutect2, varscan2
- NOS1 | c.3505C>A p.L1169M | Missense Mutation (SNP) | VAF 153/265 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100500452, COSV57623282; called by muse, mutect2, varscan2
- NQO2 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV100583181; called by muse, mutect2, varscan2
- NRG3 | c.824-1G>T p.X275_splice | Splice Site (SNP) | VAF 33/209 reads (16%) | catalogued as COSV64547073; called by muse, mutect2, varscan2
- NRK | c.3734T>C p.I1245T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54596550, COSV99687483; called by muse, varscan2
- NRK | c.3797C>G p.S1266* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99687488, COSV99688076; called by muse, varscan2
- NRXN1 | c.2943A>T p.K981N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.134); catalogued as COSV100454631; called by muse, mutect2, varscan2
- NTRK3 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.233); catalogued as COSV100446343; called by muse, mutect2, varscan2
- NUP160 | c.1056G>T p.M352I | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs752625519, COSV101021439; called by muse, mutect2, varscan2
- NXPE4 | c.997G>A p.A333T (on ENST00000375478 / NM_001077639.2; = p.A49T on NM_017678.3) | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV100970401; called by muse, mutect2, varscan2
- OGFR | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99284031; called by muse, mutect2, varscan2
- OLFM3 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 72/85 reads (85%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as rs761195734, COSV100129305; called by muse, mutect2, varscan2
- OPN4 | c.185C>A p.T62K | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); catalogued as rs185200496, COSV99618287; called by muse, mutect2, varscan2
- OPN5 | c.635C>A p.T212K | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99789810; called by muse, mutect2, varscan2
- OPRPN | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.263); catalogued as COSV101271085, COSV101271112; called by muse, mutect2, varscan2
- OR10K2 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs765832548, COSV100149470; called by muse, mutect2, varscan2
- OR11H1 | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs563714787, COSV53272511; called by muse, mutect2, varscan2
- OR11L1 | c.415G>T p.G139W | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as COSV100869420, COSV63314391; called by muse, mutect2, varscan2
- OR12D3 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101011238; called by muse, mutect2, varscan2
- OR13F1 | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV58250887, COSV58251437; called by muse, mutect2, varscan2
- OR13H1 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs768324195, COSV100088227; called by muse, mutect2, varscan2
- OR2H1 | c.757G>C p.V253L | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.578); catalogued as COSV101009838; called by muse, mutect2, varscan2
- OR2L13 | c.80T>A p.L27* | Nonsense Mutation (SNP) | VAF 122/285 reads (43%) | catalogued as COSV100813733; called by muse, mutect2, varscan2
- OR2L2 | c.845C>A p.P282Q | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100823501; called by muse, mutect2, varscan2
- OR2W3 | c.581C>A p.A194D | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.392); catalogued as COSV100831664; called by muse, mutect2
- OR4A16 | c.899G>T p.W300L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as COSV100125175; called by muse, mutect2, varscan2
- OR4A5 | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV100157049, COSV60522998, COSV60523794; called by muse, mutect2, varscan2
- OR56A4 | c.958A>T p.R320W | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100417549; called by muse, mutect2, varscan2
- OR6C76 | c.756C>A p.C252* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as COSV100094043; called by muse, mutect2, varscan2
- OR6K2 | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV100656773; called by muse, mutect2, varscan2
- OR6X1 | c.869T>C p.I290T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100020513; called by muse, mutect2, varscan2
- OR8B3 | c.206T>A p.I69N | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100660399; called by muse, mutect2, varscan2
- P4HA1 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | catalogued as COSV99696815; called by muse, mutect2, varscan2
- PANK1 | c.1297G>C p.V433L (on ENST00000307534 / NM_148977.2; = p.V208L on NM_138316.4) | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV100285602; called by muse, mutect2, varscan2
- PCDHA6 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.141); catalogued as COSV100971436; called by muse, mutect2, varscan2
- PCDHB16 | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53367598, COSV99501893; called by muse, mutect2, varscan2
- PCDHGB6 | c.274C>A p.R92S | Missense Mutation (SNP) | VAF 82/113 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53961237, COSV53989375, COSV99536517; called by muse, mutect2, varscan2
- PCLO | c.12028G>T p.D4010Y | Missense Mutation (SNP) | VAF 82/290 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100430409, COSV100431303; called by muse, mutect2, varscan2
- PDGFRB | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs765383598, COSV99940486; called by muse, mutect2, varscan2
- PEAK1 | c.4077G>C p.K1359N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100432884, COSV56932592; called by muse, mutect2, varscan2
- PHEX | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 23/29 reads (79%) | catalogued as COSV101039568; called by muse, mutect2, varscan2
- PHKG1 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV99818167; called by muse, mutect2, varscan2
- PILRB | c.212G>C p.W71S | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100167009, COSV60333752; called by muse, mutect2, varscan2
- PKHD1L1 | c.6271C>A p.P2091T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101006003; called by muse, mutect2, varscan2
- PLCB3 | c.2857C>T p.P953S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54192357; called by muse, mutect2, varscan2
- PLPPR4 | c.408+1G>C p.X136_splice | Splice Site (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100927051; called by muse, mutect2, varscan2
- PLXNA2 | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.055); catalogued as COSV100885385; called by muse, mutect2, varscan2
- PLXNA4 | c.2549G>T p.G850V | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV100323882, COSV100325926, COSV58164562; called by muse, mutect2, varscan2
- POSTN | c.152G>C p.G51A | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101123311; called by muse, mutect2, varscan2
- PPCDC | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as COSV100738830; called by muse, mutect2, varscan2
- PPP1R16A | c.1331C>A p.P444H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV99477558; called by mutect2, varscan2
- PPP1R3A | c.393G>T p.E131D | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99492681; called by muse, mutect2, varscan2
- PRG4 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.161); catalogued as COSV63355445; called by muse, mutect2, varscan2
- PRTG | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs781574830, COSV101221358; called by muse, mutect2, varscan2
- PSD3 | c.829G>T p.G277W | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV100495885; called by muse, mutect2, varscan2
- PSD4 | c.639A>C p.E213D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV99831064; called by muse, mutect2, varscan2
- PSG2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 144/407 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.034); catalogued as rs372916591, COSV61546242; called by muse, mutect2, varscan2
- PSG4 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99736885; called by muse, mutect2, varscan2
- PTPRM | c.4129G>C p.E1377Q | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV100156768; called by muse, mutect2, varscan2
- PTPRN2 | c.618del p.S208Pfs*35 | Frame Shift Del (DEL) | VAF 34/96 reads (35%) | catalogued as COSV67059771; called by mutect2, pindel
- PTPRT | c.3511A>C p.N1171H | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as COSV100626761; called by muse, mutect2, varscan2
- RAB40AL | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99505074; called by muse, mutect2, varscan2
- RAP1GDS1 | c.816G>T p.E272D (on ENST00000408927 / NM_001100427.2; = p.E273D on NM_021159.5) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV99216912; called by muse, mutect2, varscan2
- RASA3 | c.530G>T p.R177I | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100480398, COSV61866556; called by muse, mutect2, varscan2
- RASAL2 | c.389G>T p.R130M | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100862572; called by muse, mutect2, varscan2
- RASD2 | c.631G>C p.A211P | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.143); catalogued as COSV53353440, COSV99332763; called by muse, mutect2, varscan2
- RASGRP3 | c.611G>T p.W204L | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748550600, COSV101274740, COSV67820486; called by muse, mutect2, varscan2
- RC3H1 | c.1985A>T p.Y662F | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99281282; called by muse, mutect2, varscan2
- RGS13 | c.278C>A p.P93Q | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.515); catalogued as COSV101232224; called by muse, mutect2, varscan2
- RHOD | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as rs763430377, COSV99074641; called by muse, mutect2, varscan2
- RILP | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs1297586816; called by muse, mutect2, varscan2
- RIT1 | c.605G>C p.S202T | Missense Mutation (SNP) | VAF 99/727 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100851171; called by muse, mutect2, varscan2
- RNF112 | c.308A>C p.Q103P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101518341; called by muse, mutect2, varscan2
- ROR2 | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.968); catalogued as COSV100995771; called by muse, mutect2, varscan2
- RPL10L | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100022527; called by muse, mutect2, varscan2
- RPL29 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs201202375, COSV99587602; called by muse, mutect2, varscan2
- RTL4 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 96/152 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV100465881, COSV61205874; called by muse, mutect2, varscan2
- RYBP | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV101523292; called by muse, mutect2, varscan2
- RYR2 | c.2284A>T p.S762C | Missense Mutation (SNP) | VAF 89/386 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100769682; called by muse, mutect2, varscan2
- RYR3 | c.5540A>T p.E1847V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV101212582; called by muse, mutect2, varscan2
- SAMD9 | c.3523T>A p.Y1175N | Missense Mutation (SNP) | VAF 94/319 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV101180203; called by muse, mutect2, varscan2
- SCN1A | c.3977C>A p.A1326D (on ENST00000303395 / NM_001202435.3; = p.A1315D on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM0910328, CM136044, COSV100320198; called by muse, mutect2, varscan2
- SCPEP1 | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 78/406 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV51855389; called by muse, mutect2, varscan2
- SEMA4A | c.1711G>C p.V571L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100740557; called by muse, mutect2, varscan2
- SEPTIN1 | c.756C>A p.D252E (on ENST00000321367; = p.D205E on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/156 reads (54%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.973); catalogued as COSV100363049; called by muse, mutect2, varscan2
- SERPINB3 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1319308328, COSV99379799; called by muse, mutect2, varscan2
- SH3PXD2B | c.1248G>T p.W416C | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100287921; called by muse, mutect2, varscan2
- SLC10A2 | c.707C>A p.A236E | Missense Mutation (SNP) | VAF 116/172 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV55360193, COSV55360694; called by muse, mutect2, varscan2
- SLC16A5 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV100317060; called by muse, mutect2, varscan2
- SLC17A2 | c.734A>T p.E245V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99614244; called by muse, mutect2, varscan2
- SLC17A4 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100930563; called by muse, mutect2, varscan2
- SLC22A16 | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100397416; called by muse, varscan2
- SLC25A31 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745363139, COSV99829406; called by muse, mutect2, varscan2
- SLC25A40 | c.632-1G>T p.X211_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100353643; called by muse, mutect2, varscan2
- SLC25A40 | c.632-2A>T p.X211_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100353644; called by muse, mutect2, varscan2
- SLC27A3 | c.1961C>T p.T654I (on ENST00000271857; = p.T526I on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99669897; called by muse, mutect2, varscan2
- SLC43A2 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 80/102 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100024906; called by muse, mutect2, varscan2
- SLC5A10 | c.1083G>A p.M361I (on ENST00000395645 / NM_001042450.4; = p.M377I on NM_152351.5) | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV100525047; called by muse, mutect2, varscan2
- SLC7A8 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100328395; called by muse, mutect2, varscan2
- SLC8A1 | c.2405C>G p.A802G | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100245325; called by muse, mutect2, varscan2
- SLC8A3 | c.2275G>A p.A759T (on ENST00000381269 / NM_183002.3; = p.A757T on NM_033262.4) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs780117754, COSV53691876; called by muse, mutect2, varscan2
- SLMAP | c.1654A>T p.T552S (on ENST00000428312 / NM_001377924.1; = p.T614S on NM_007159.5) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as COSV99908410; called by muse, mutect2, varscan2
- SMG6 | c.224A>T p.K75I | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.296); catalogued as rs746437973, COSV99558072; called by muse, mutect2, varscan2
- SOD2 | c.377G>C p.G126A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100496608; called by muse, mutect2
- SPATA31D1 | c.1759C>A p.P587T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.885); catalogued as COSV100782736; called by muse, mutect2, varscan2
- SPSB1 | c.346G>T p.G116W | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100049397; called by muse, mutect2, varscan2
- SPTBN1 | c.2927A>G p.K976R | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0.035); catalogued as COSV100442411; called by muse, mutect2, varscan2
- ST6GAL2 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | PolyPhen benign (0.015); catalogued as COSV64529680; called by muse, mutect2, varscan2
- STX2 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99892695; called by muse, mutect2, varscan2
- STYXL2 | c.1596C>A p.N532K | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99608774, COSV99609074; called by muse, mutect2, varscan2
- STYXL2 | c.1893G>C p.E631D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99609075; called by muse, mutect2, varscan2
- SVEP1 | c.2980C>A p.L994M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100237834; called by muse, mutect2, varscan2
- TBC1D28 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV100560971; called by muse, mutect2, varscan2
- TCF21 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99399583, COSV99399613; called by muse, varscan2
- TG | c.3461G>A p.S1154N | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1360662478, COSV99600408; called by muse, mutect2, varscan2
- TMEM106C | c.730G>T p.G244* | Nonsense Mutation (SNP) | VAF 65/124 reads (52%) | catalogued as COSV99873390; called by muse, mutect2, varscan2
- TOGARAM2 | c.1652C>A p.A551D | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101091065; called by muse, mutect2
- TRHDE | c.1588-1G>C p.X530_splice | Splice Site (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99670368; called by muse, mutect2, varscan2
- TRIM16L | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as COSV67459790; called by muse, mutect2, varscan2
- TRIM21 | c.21G>T p.L7F | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99587655; called by muse, mutect2, varscan2
- TRIM48 | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101338262; called by muse, mutect2, varscan2
- TRIM71 | c.2554G>T p.D852Y | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101070415, COSV67472660; called by muse, mutect2, varscan2
- TRIP6 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV99307749; called by muse, mutect2, varscan2
- TRPC4 | c.1604A>T p.N535I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100156624; called by muse, mutect2, varscan2
- TSHZ3 | c.2045G>T p.S682I | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99551320; called by muse, mutect2, varscan2
- TSHZ3 | c.1700C>A p.S567* | Nonsense Mutation (SNP) | VAF 41/148 reads (28%) | catalogued as COSV99551323; called by muse, mutect2, varscan2
- TSPAN16 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.184); catalogued as COSV100368323; called by muse, mutect2, varscan2
- TSPAN2 | c.566T>G p.I189S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV101049900, COSV65690575; called by muse, mutect2, varscan2
- TTC29 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100283640; called by muse, mutect2, varscan2
- TTLL7 | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.272); catalogued as COSV99552281; called by muse, mutect2, varscan2
- TTN | c.16598A>C p.K5533T (on ENST00000591111; = p.K4606T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | PolyPhen probably damaging (0.943); catalogued as COSV100608741; called by muse, mutect2, varscan2
- TTN | c.15229G>T p.G5077C (on ENST00000591111; = p.G4150C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | PolyPhen possibly damaging (0.847); catalogued as COSV100608743; called by muse, mutect2, varscan2
- UBE3D | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52755276; called by muse, mutect2, varscan2
- UBXN4 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99739001; called by muse, mutect2, varscan2
- USH2A | c.3303T>G p.D1101E | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs968315321, COSV100233350; called by muse, mutect2, varscan2
- USP29 | c.2423A>T p.K808M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV99518005; called by muse, mutect2, varscan2
- USP33 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62469397; called by muse, mutect2, varscan2
- UTRN | c.5918G>T p.R1973M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV100839841; called by muse, mutect2, varscan2
- VIP | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.068); catalogued as rs763123554, COSV100923931; called by muse, mutect2, varscan2
- VNN2 | c.368C>A p.A123E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100426766; called by muse, mutect2, varscan2
- WAS | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1215457658, COSV64996832; called by muse, mutect2, varscan2
- WDR64 | c.1983G>T p.L661F | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as COSV100843742, COSV63796997; called by muse, mutect2, varscan2
- WNK3 | c.3437C>T p.S1146F | Missense Mutation (SNP) | VAF 128/137 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100671238; called by muse, mutect2, varscan2
- WNK3 | c.1951G>T p.V651F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.169); catalogued as COSV100671241; called by muse, mutect2, varscan2
- ZBED8 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV101283495; called by muse, mutect2, varscan2
- ZFHX4 | c.1230dup p.L411Afs*3 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | catalogued as rs761578656; called by mutect2, varscan2
- ZIM3 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.232); catalogued as COSV99518008; called by muse, mutect2, varscan2
- ZNF208 | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.833); catalogued as COSV101237000; called by muse, mutect2, varscan2
- ZNF275 | c.1048G>C p.A350P | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100936214; called by muse, mutect2, varscan2
- ZNF285 | c.179C>A p.A60E | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs117953191; called by muse, mutect2, varscan2
- ZNF287 | c.1579C>G p.Q527E | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as COSV101209373; called by muse, mutect2, varscan2
- ZNF292 | c.4941G>T p.L1647F | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV100370239; called by muse, mutect2, varscan2
- ZNF354C | c.809A>C p.K270T | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100203611; called by muse, mutect2, varscan2
- ZNF394 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 57/89 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs1192652644, COSV100460144; called by muse, mutect2, varscan2
- ZNF470 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100401215; called by muse, mutect2, varscan2
- ZNF80 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.17); catalogued as COSV100352006; called by muse, mutect2, varscan2
- ZNF83 | c.1066C>A p.R356S | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV99991323; called by muse, varscan2
- ZNF883 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101432557; called by muse, mutect2, varscan2
- ZP4 | c.1410C>A p.N470K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs536140661, COSV100850661; called by muse, varscan2
- ZSWIM4 | c.2695C>T p.R899C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs776380959, COSV54325151; called by muse, mutect2, varscan2
- CUZD1 | c.1253dup p.L418Ffs*10 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.910G>T p.V304L | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- DCLK1 | c.1412del p.G471Efs*25 | Frame Shift Del (DEL) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- FLOT1 | c.938_940delinsTT p.A313Vfs*15 | Frame Shift Del (DEL) | VAF 62/642 reads (10%) | called by pindel, varscan2*
- FRG2C | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 81/139 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- IGHV3-53 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- MMP28 | c.819G>C p.W273C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2
- MMP3 | c.270del p.R91Gfs*29 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- NFRKB | c.3456del p.I1153Sfs*38 (on ENST00000446488 / NM_001143835.2; = p.I1178Sfs*38 on NM_006165.3) | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- NSFL1C | c.293del p.G98Afs*35 | Frame Shift Del (DEL) | VAF 86/288 reads (30%) | called by mutect2, pindel, varscan2
- OR10G4 | c.468dup p.V157Cfs*23 | Frame Shift Ins (INS) | VAF 73/261 reads (28%) | called by mutect2, pindel, varscan2
- PADI4 | c.176dup p.K60Efs*27 | Frame Shift Ins (INS) | VAF 47/107 reads (44%) | called by mutect2, pindel, varscan2
- POLR3A | c.1840_1841del p.R614Gfs*21 | Frame Shift Del (DEL) | VAF 175/329 reads (53%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.176G>C p.W59S | Missense Mutation (SNP) | VAF 42/577 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPANXB1 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 54/514 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); called by muse, varscan2
- SPATA31D1 | c.1074del p.W358Cfs*33 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SYNRG | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.049); called by mutect2, varscan2
- TBC1D9 | c.1076del p.K359Rfs*20 | Frame Shift Del (DEL) | VAF 74/214 reads (35%) | called by mutect2, pindel, varscan2
- ZNF536 | c.1665_1667delinsTT p.G556Wfs*13 | Frame Shift Del (DEL) | VAF 41/110 reads (37%) | called by pindel, varscan2*
- AARS2 | c.2418G>T p.R806= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV99771396; called by muse, mutect2, varscan2
- ABCA13 | c.2358T>C p.S786= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV101330022; called by muse, mutect2, varscan2
- AGBL5 | c.1632G>T p.P544= | Silent (SNP) | VAF 190/282 reads (67%) | catalogued as COSV100549043; called by muse, mutect2, varscan2
- AHNAK2 | c.9729C>A p.G3243= | Silent (SNP) | VAF 52/128 reads (41%) | catalogued as rs751770947, COSV60916401; called by muse, mutect2, varscan2
- AIRE | c.573T>A p.A191= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV99381095; called by muse, mutect2, varscan2
- ANKRD30A | c.534A>C p.L178= (on ENST00000611781; = p.L122= on NM_052997.2) | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV100653369; called by muse, mutect2, varscan2
- ANKS1B | c.1194G>T p.T398= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs374453521, COSV100244908; called by muse, mutect2, varscan2
- ARNT2 | c.531G>A p.E177= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as COSV100308904; called by muse, mutect2, varscan2
- ASTN1 | c.1623C>A p.G541= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99921288; called by muse, mutect2, varscan2
- B4GALNT4 | c.2346G>T p.P782= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100327455; called by muse, mutect2, varscan2
- BCAT1 | c.883C>T p.L295= | Silent (SNP) | VAF 106/152 reads (70%) | catalogued as COSV53917663; called by muse, mutect2, varscan2
- BMPR2 | c.45A>G p.P15= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as rs1289095937, COSV101001433; called by muse, mutect2, varscan2
- BTN1A1 | c.84C>G p.P28= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99764325; called by muse, mutect2, varscan2
- CACNA1A | c.2013C>T p.N671= | Silent (SNP) | VAF 127/308 reads (41%) | catalogued as rs779250946, COSV64213264; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1F | c.999C>A p.T333= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV100544688; called by muse, mutect2, varscan2
- CALML5 | c.156C>A p.L52= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100981187; called by muse, mutect2
- CARD6 | c.750A>T p.S250= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV99620684; called by muse, mutect2
- CCDC91 | c.126T>C p.L42= | Silent (SNP) | VAF 89/461 reads (19%) | catalogued as COSV100081683; called by muse, mutect2, varscan2
- CHD4 | c.3618C>G p.L1206= (on ENST00000357008 / NM_001363606.2; = p.L1219= on NM_001273.5) | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as rs1231877197, COSV100537809; called by muse, mutect2, varscan2
- CHD4 | c.3306G>T p.P1102= (on ENST00000357008 / NM_001363606.2; = p.P1115= on NM_001273.5) | Silent (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- CITED2 | c.264C>T p.A88= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV100863106; called by muse, mutect2, varscan2
- CLSTN2 | c.408A>T p.T136= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV101515670, COSV71717726; called by muse, mutect2, varscan2
- CRISPLD2 | c.579G>T p.A193= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as rs373699416, COSV99295587; called by muse, mutect2, varscan2
- CRX | c.462C>G p.T154= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV99704442; called by muse, mutect2, varscan2
- CTNNA2 | c.979C>A p.R327= | Silent (SNP) | VAF 56/90 reads (62%) | catalogued as COSV100783486, COSV63557409; called by muse, mutect2, varscan2
- DCAF12L2 | c.45G>T p.A15= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100758569; called by muse, varscan2
- DCAF4L2 | c.327C>G p.T109= | Silent (SNP) | VAF 82/151 reads (54%) | catalogued as COSV100150796, COSV60477390; called by muse, mutect2, varscan2
- DCDC1 | c.2394C>A p.T798= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV100663228; called by muse, mutect2, varscan2
- DEFB125 | c.144T>C p.L48= | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as COSV101217516; called by muse, mutect2, varscan2
- DGKI | c.1620A>T p.T540= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV99933852; called by muse, mutect2, varscan2
- DTX4 | c.1818C>A p.A606= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99915304; called by muse, mutect2, varscan2
- EFCAB13 | c.2490C>T p.S830= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100516502; called by muse, mutect2, varscan2
- EP400 | c.3261A>T p.T1087= | Silent (SNP) | VAF 67/117 reads (57%) | catalogued as rs749982667, COSV100201051; called by muse, mutect2, varscan2
- FAM47B | c.1026C>A p.S342= | Silent (SNP) | VAF 30/36 reads (83%) | catalogued as COSV100264272; called by muse, mutect2, varscan2
- FAT4 | c.12018G>A p.T4006= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs368157923; called by muse, mutect2, varscan2
- GABRA6 | c.1242C>A p.T414= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV50888438; called by muse, mutect2, varscan2
- GABRB3 | c.1335G>A p.V445= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100159434; called by muse, mutect2, varscan2
- GJB3 | c.339C>T p.C113= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs376459246; called by muse, mutect2, varscan2
- GJD2 | c.747G>A p.E249= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV51747294, COSV99290692; called by muse, mutect2, varscan2
- GLMP | c.513C>T p.A171= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as COSV99827870; called by muse, mutect2, varscan2
- GPC5 | c.1428T>A p.P476= | Silent (SNP) | VAF 34/172 reads (20%) | catalogued as COSV100993631; called by muse, mutect2, varscan2
- GPR83 | c.696T>C p.A232= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV54720242, COSV99703661; called by muse, mutect2, varscan2
- GSDMC | c.81A>T p.L27= | Silent (SNP) | VAF 96/303 reads (32%) | catalogued as COSV99415895; called by muse, mutect2, varscan2
- HAT1 | c.837C>T p.S279= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs1558980402, COSV99907915; called by muse, mutect2, varscan2
- HELLS | c.627A>G p.P209= | Silent (SNP) | VAF 72/189 reads (38%) | catalogued as COSV99491982; called by muse, mutect2, varscan2
- HK3 | c.675C>T p.G225= | Silent (SNP) | VAF 78/94 reads (83%) | catalogued as COSV99458393; called by muse, mutect2, varscan2
- HPD | c.732G>A p.A244= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as COSV100000083; called by muse, mutect2, varscan2
- HSD3B2 | c.54C>A p.I18= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as rs777605448, COSV101027465, COSV65592765; called by muse, mutect2, varscan2
- IGHV1-58 | c.183A>G p.G61= | Silent (SNP) | VAF 44/57 reads (77%) | catalogued as rs1555552424; called by muse, mutect2, varscan2
- INSR | c.3159C>T p.R1053= | Silent (SNP) | VAF 50/157 reads (32%) | catalogued as rs376505773; called by muse, mutect2, varscan2
- ITGB2 | c.243C>A p.P81= | Silent (SNP) | VAF 90/150 reads (60%) | catalogued as COSV100185801; called by muse, varscan2
- KCNA4 | c.1890G>A p.Q630= | Silent (SNP) | VAF 54/153 reads (35%) | catalogued as COSV100068856, COSV60251073; called by muse, mutect2, varscan2
- KCND3 | c.201C>A p.G67= | Silent (SNP) | VAF 54/63 reads (86%) | catalogued as COSV100137200; called by muse, mutect2, varscan2
- KLK2 | c.468C>A p.G156= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100319931; called by muse, mutect2, varscan2
- KRT77 | c.1116A>G p.G372= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV100527064; called by muse, mutect2, varscan2
- KRTAP8-1 | c.174G>T p.S58= | Silent (SNP) | VAF 104/195 reads (53%) | catalogued as rs768734553, COSV100297815, COSV100297871; called by muse, mutect2, varscan2
- LCA5 | c.2040A>C p.A680= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100878239; called by muse, mutect2, varscan2
- LRP1B | c.6972C>A p.A2324= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV101255795; called by muse, mutect2, varscan2
- LRRC7 | c.999T>A p.I333= (on ENST00000651989 / NM_001370785.2; = p.I300= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as COSV50605845, COSV99226210; called by muse, mutect2, varscan2
- MAFB | c.180C>T p.L60= | Silent (SNP) | VAF 50/117 reads (43%) | catalogued as COSV64826470; called by muse, mutect2, varscan2
- MAMDC2 | c.1782T>A p.T594= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV101015444; called by muse, mutect2, varscan2
- MEST | c.741C>T p.V247= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV99784219; called by muse, mutect2, varscan2
- MPP4 | c.894C>T p.C298= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs758311354, COSV100206770; called by muse, mutect2, varscan2
- MUC16 | c.11757T>G p.T3919= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs1398667810, COSV101199556; called by muse, mutect2, varscan2
- MYH8 | c.243T>A p.P81= | Silent (SNP) | VAF 90/99 reads (91%) | catalogued as COSV101238382; called by muse, mutect2, varscan2
- MYLK3 | c.966C>T p.A322= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV101189108; called by muse, mutect2, varscan2
- NBEAL2 | c.2319G>T p.V773= | Silent (SNP) | VAF 20/20 reads (100%) | catalogued as COSV99435700; called by muse, mutect2, varscan2
- NKX6-2 | c.798C>A p.V266= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100888334; called by muse, mutect2, varscan2
- NOP14 | c.183G>T p.R61= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as COSV100054574; called by muse, mutect2, varscan2
- NRCAM | c.2709C>T p.I903= (on ENST00000379028 / NM_001371124.1; = p.I887= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV61046790; called by muse, mutect2, varscan2
- NTRK3 | c.414G>T p.R138= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100446342; called by muse, mutect2, varscan2
- OR52E6 | c.882G>T p.G294= | Silent (SNP) | VAF 46/159 reads (29%) | catalogued as COSV100259291; called by muse, mutect2, varscan2
- OR56A3 | c.678G>T p.L226= | Silent (SNP) | VAF 54/261 reads (21%) | catalogued as COSV100290184; called by muse, mutect2, varscan2
- OR5D16 | c.180C>G p.P60= | Silent (SNP) | VAF 59/271 reads (22%) | catalogued as COSV101003919; called by muse, mutect2, varscan2
- OR5P3 | c.24T>C p.T8= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100103057, COSV100103114; called by muse, mutect2, varscan2
- OTOA | c.3405G>C p.S1135= (on ENST00000286149; = p.S1121= on NM_144672.4) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV53754136; called by mutect2, varscan2
- PANK4 | c.213A>T p.T71= | Silent (SNP) | VAF 64/114 reads (56%) | catalogued as COSV101022393; called by muse, mutect2, varscan2
- PCARE | c.642G>T p.L214= | Silent (SNP) | VAF 32/279 reads (11%) | catalogued as COSV100527485; called by muse, mutect2, varscan2
- PCDH7 | c.1743C>A p.I581= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100688059; called by muse, mutect2, varscan2
- PCDHA10 | c.528T>C p.Y176= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100249901; called by muse, mutect2, varscan2
- PDHA2 | c.1140A>T p.P380= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV99756802; called by muse, mutect2, varscan2
- PDIK1L | c.255C>T p.S85= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs1310609066, COSV100957678; called by muse, mutect2, varscan2
- PKD2L2 | c.1395C>A p.I465= | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as COSV99296218; called by muse, mutect2, varscan2
- PLXNA4 | c.5034G>T p.L1678= | Silent (SNP) | VAF 132/521 reads (25%) | catalogued as COSV100323879; called by muse, mutect2, varscan2
- POLD2 | c.717C>G p.S239= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99788728; called by muse, mutect2, varscan2
- POTEE | c.258C>T p.H86= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as rs757065263; called by muse, mutect2, varscan2
- POU3F4 | c.657G>T p.L219= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as COSV100937212; called by muse, mutect2, varscan2
- POU4F2 | c.72C>A p.P24= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99850485; called by muse, mutect2, varscan2
- POU4F2 | c.930T>C p.N310= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as COSV99850487; called by muse, mutect2, varscan2
- PPP1R13L | c.1416A>T p.P472= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100714734; called by muse, mutect2, varscan2
- PRKCG | c.2085C>T p.P695= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV99668890; called by muse, mutect2, varscan2
- PRSS55 | c.372G>T p.L124= | Silent (SNP) | VAF 51/207 reads (25%) | catalogued as COSV100153751; called by muse, mutect2, varscan2
- RAB9B | c.30C>T p.V10= | Silent (SNP) | VAF 66/264 reads (25%) | catalogued as COSV99686028, COSV99686036; called by muse, mutect2, varscan2
- RALGPS2 | c.312T>A p.V104= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as COSV100243823; called by muse, mutect2, varscan2
- RHBG | c.1218G>T p.V406= | Silent (SNP) | VAF 104/204 reads (51%) | catalogued as COSV99659485; called by muse, mutect2, varscan2
- RMI1 | c.276G>A p.L92= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs759040710, COSV100366182; called by muse, mutect2, varscan2
- SEMA4A | c.1275C>A p.G425= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV100740555; called by muse, mutect2, varscan2
- SH3BP2 | c.576A>T p.G192= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100696914; called by muse, mutect2, varscan2
- SLC12A1 | c.1692G>A p.L564= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV101118583; called by muse, mutect2, varscan2
- SLC22A16 | c.732C>A p.V244= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as COSV100397417; called by muse, varscan2
- SORL1 | c.2643G>T p.L881= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as COSV99493605; called by muse, mutect2, varscan2
- SOX6 | c.2211A>T p.T737= (on ENST00000528429 / NM_001145819.2; = p.T710= on NM_017508.3) | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs1170865282, COSV100321933; called by muse, mutect2, varscan2
- SPATA17 | c.301C>A p.R101= | Silent (SNP) | VAF 62/194 reads (32%) | catalogued as COSV100861061, COSV65121568; called by muse, mutect2, varscan2
- SYNDIG1L | c.570C>A p.A190= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV100526463; called by muse, mutect2, varscan2
- TBC1D28 | c.225C>G p.T75= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as COSV100560973; called by muse, mutect2, varscan2
- TNIK | c.2709G>A p.L903= | Silent (SNP) | VAF 75/213 reads (35%) | catalogued as COSV52671770, COSV99456741; called by muse, mutect2, varscan2
- TOGARAM2 | c.1212G>T p.R404= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101091064; called by muse, varscan2
- TOGARAM2 | c.1653C>T p.A551= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs1462352951, COSV101091066; called by muse, mutect2, varscan2
- TPBG | c.603G>T p.A201= | Silent (SNP) | VAF 85/102 reads (83%) | catalogued as COSV100869770; called by muse, mutect2, varscan2
- UNC13A | c.2448T>C p.H816= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs755687120, COSV99408015; called by muse, mutect2, varscan2
- UNC5A | c.1806C>A p.A602= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV99458389; called by muse, mutect2, varscan2
- XPO1 | c.225G>T p.T75= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV101294200, COSV68945939; called by muse, mutect2, varscan2
- ZC3H4 | c.747C>A p.G249= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99452178; called by muse, mutect2, varscan2
- ZNF229 | c.1734G>C p.G578= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV99350341; called by muse, mutect2, varscan2
- ZNF329 | c.870A>G p.L290= | Silent (SNP) | VAF 45/160 reads (28%) | catalogued as COSV100798717; called by muse, mutect2, varscan2
- ZNF626 | c.30C>A p.A10= | Silent (SNP) | VAF 99/261 reads (38%) | catalogued as COSV99391690; called by muse, mutect2, varscan2
- ZNF827 | c.3120A>T p.I1040= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV101061300; called by muse, mutect2, varscan2
- AF241726.1 | c.172-444712C>T | Intron (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100656025; called by muse, mutect2, varscan2
- ANKRD33 | c.665-53G>T | Intron (SNP) | VAF 63/113 reads (56%) | catalogued as COSV100001251; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502587 ins G | 5'Flank (INS) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- MAGEC3 | c.1124-124G>A | Intron (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100025085; called by muse, mutect2, varscan2
- MASP1 | c.1303+5093G>C | Intron (SNP) | VAF 26/52 reads (50%) | catalogued as COSV99962204; called by muse, mutect2, varscan2
- MIR487A | n.56C>A | RNA (SNP) | VAF 29/39 reads (74%) | called by muse, mutect2, varscan2
- OFCC1 | n.393-2902A>T | Intron (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- PCDH15 | c.3374-1840T>A | Intron (SNP) | VAF 144/372 reads (39%) | catalogued as rs909730703, COSV100219583; called by muse, mutect2, varscan2
- SLC5A4 | c.-1C>A | 5'UTR (SNP) | VAF 89/219 reads (41%) | catalogued as COSV56668560, COSV99831873; called by muse, mutect2, varscan2
- SLFN5 | c.-1G>A | 5'UTR (SNP) | VAF 57/131 reads (44%) | catalogued as rs1206243361, COSV100249658; called by muse, mutect2, varscan2
- SSPOP | n.14023G>T | RNA (SNP) | VAF 29/100 reads (29%) | catalogued as COSV100947291; called by muse, mutect2, varscan2
- SSPOP | n.14360del | RNA (DEL) | VAF 35/188 reads (19%) | called by mutect2, pindel, varscan2
